Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5199, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5199-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Left renal mass.

TCGA-BP-5199

Specimens Submitted:

- 1: KIDNEY, LEFT AND PROXIMAL URETER; TOTAL NEPHRECTOMY ✓
2: LYMPH NODES, PARA-AORTIC; EXCISION ✓

DIAGNOSIS:

1. KIDNEY, LEFT AND PROXIMAL URETER; TOTAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
With prominent sarcomatoid features

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 7.6 cm. ✓

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney ✓

2. LYMPH NODES, PARA-AORTIC; EXCISION:

Lymph Nodes:

Not involved

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Number of nodes examined:4

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	AE1:AE3	
	CA-1X.	
	CD31	
	CD34	
	IMM RECUT	
	NEG CONT	

Gross Description:

1)The specimen is received fresh labeled "left kidney and proximal ureter" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 645 g in total. The kidney measures 15.2 x 8 x 5.9 cm. The attached ureter measures 2.5 cm in length and 0.5 cm in diameter. The attached renal vein measures 3.1 cm in length and 1.2 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a well-circumscribed multi-lobulated yellow golden hemorrhagic mass measuring 7.6 x 6.0 x 5.5 cm. The mass is located at the upper pole of the left the kidney and it appears to be abutting and confined within the renal capsule. The renal artery, vein and ureters are not involved by the tumor. The mass invades the renal sinus fat, it is about 1.5 cm from the renal hilar fat. Tumor grossly has 40% hemorrhage and 20 % necrosis. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.8cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections. Photos are taken.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

ADD--additional section of ureteral margin and sinus fat

2). The specimen is received in formalin, labeled "paraortic lymph nodes" and consists of several red-tan lymph nodes ranging from 1.5 to 4.3 cm in greatest dimension, which are entirely submitted.

Summary of sections:

BLN1 -- bisected lymph node number one

BLN2 -- bisected lymph node number two

LLN-largest lymph node, sectioned and submitted in seven cassettes

SLN-trisected lymph node

Summary of Sections:

Part 1: KIDNEY, LEFT AND PROXIMAL URETER; TOTAL NEPHRECTOMY

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Block	Sect. Site	PCs
4	add	4
1	k	1
1	rp	1
6	t	6
3	thf	3
2	tk	2
3	tsf	3
1	uvm	1

Part 2: LYMPH NODES, PARA-AORTIC; EXCISION

Block	Sect. Site	PCs
1	bln1	1
1	bln2	1
7	lln	7
3	sln	3

Source: NCI Genomic Data Commons file 0807c06e-a8cd-4329-aaed-da0a1dbf4e0d (TCGA-BP-5199.C12FD399-C39A-4383-B521-21A020D035D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).